Somatic mutation profile of tumor specimen TCGA-AC-A8OQ-01A (aliquot TCGA-AC-A8OQ-01A-11D-A41F-09) from TCGA case TCGA-AC-A8OQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-AC-A8OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6719ee14-59f6-4083-ab7d-81e11d766cbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A8OQ-10A (Blood Derived Normal), aliquot TCGA-AC-A8OQ-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2586c7f8-a1e2-48e9-9a65-7822faccf0c3

The open-access MAF lists 92 somatic variants for this specimen: 70 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 3, Intron 2, 5'Flank 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs374849789; called by muse, mutect2, varscan2
- ADAM32 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.07); catalogued as COSV101165437; called by muse, mutect2, varscan2
- ARFGEF3 | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99294087, COSV99294113; called by muse, mutect2, varscan2
- ASCC3 | c.4738G>A p.A1580T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100976716; called by muse, mutect2
- AXL | c.1906C>T p.R636W (on ENST00000301178 / NM_021913.5; = p.R627W on NM_001699.6) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs756510536; called by muse, mutect2, varscan2
- BABAM2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1445947949, COSV56220125; called by muse, mutect2
- CALCOCO1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs747890587, COSV50411648; called by muse, mutect2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs768812342; called by mutect2, varscan2
- CDC14A | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781410426, COSV60561571; called by muse, mutect2
- CDH11 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339416150, COSV51752888, COSV51764246; called by muse, mutect2, varscan2
- CDK11B | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753220778, COSV100477929, COSV58336614; called by muse, mutect2, varscan2
- CELSR1 | c.8269G>A p.E2757K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as rs146465806; called by muse, mutect2
- CNTN2 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100084800, COSV100085226; called by muse, mutect2
- CNTNAP5 | c.2265C>A p.D755E | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101443777; called by muse, mutect2
- COL6A2 | c.2851G>A p.V951I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as rs111630733, COSV99385235; called by muse, mutect2, varscan2
- CSE1L | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV99522102; called by muse, mutect2
- CSMD3 | c.124A>C p.S42R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV99839101; called by muse, mutect2, varscan2
- DCHS1 | c.5978C>T p.A1993V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV55040087; called by muse, mutect2
- DENND2B | c.2801C>A p.P934Q | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567620; called by muse, mutect2
- EIF3L | c.33+1G>T p.X11_splice | Splice Site (SNP) | VAF 24/237 reads (10%) | catalogued as COSV101094597; called by muse, mutect2, varscan2
- ERN2 | c.1089C>G p.H363Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99891823; called by muse, mutect2, varscan2
- FAM120C | c.1945C>G p.P649A | Missense Mutation (SNP) | VAF 92/615 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV100070251; called by muse, mutect2, varscan2
- FERMT3 | c.1375C>T p.R459C (on ENST00000279227 / NM_178443.3; = p.R455C on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs775462582, COSV99656685; ClinVar: uncertain significance; called by muse, varscan2
- FIP1L1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV60994177; called by muse, mutect2, varscan2
- FOXA2 | c.622C>T p.R208C (on ENST00000377115 / NM_153675.3; = p.R214C on NM_021784.5) | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008413; called by muse, mutect2
- GABRG3 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100408408; called by muse, mutect2, varscan2
- HERC1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV101496697; called by muse, mutect2
- IFNA2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV101206989; called by muse, mutect2
- INSL4 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV99497163; called by muse, mutect2, varscan2
- KCNIP2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as COSV99493481; called by muse, mutect2, varscan2
- LINGO2 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV100430810; called by muse, mutect2, varscan2
- LRPPRC | c.3668G>A p.R1223K | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV99580977; called by muse, mutect2
- LRRC66 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100603020; called by muse, mutect2, varscan2
- LRRC7 | c.545A>T p.Y182F (on ENST00000651989 / NM_001370785.2; = p.Y149F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as COSV99227992; called by muse, mutect2
- MASP2 | c.251A>C p.K84T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV101280293; called by mutect2, varscan2
- MAST4 | c.4880C>T p.A1627V (on ENST00000403625 / NM_001164664.2; = p.A1438V on NM_015183.3) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1554031866, COSV99844790; called by muse, mutect2, varscan2
- MORC1 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99226786; called by muse, mutect2, varscan2
- MYO16 | c.2463G>T p.E821D | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99194147; called by muse, mutect2, varscan2
- NCOA6 | c.5524G>A p.G1842R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV100750153; called by muse, mutect2
- NFASC | c.377C>T p.T126M (on ENST00000339876 / NM_001378329.1; = p.T120M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770085499, COSV58361282; called by muse, mutect2, varscan2
- NLRC4 | c.2321A>T p.K774M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100707444; called by muse, mutect2, varscan2
- PCOLCE2 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV56000221, COSV56000858; called by muse, mutect2
- PLA2G4F | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101215242, COSV51825686; called by muse, mutect2
- PLCG2 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV63869094; called by muse, mutect2, varscan2
- PROM2 | c.1427+1G>A p.X476_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as rs200030602, COSV58298084; called by muse, mutect2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2, varscan2
- SLC22A2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.259); catalogued as COSV100871003; called by muse, mutect2, varscan2
- SLIT2 | c.3690C>G p.Y1230* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV56562103, COSV99885197; called by muse, mutect2, varscan2
- SPRY2 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101001715; called by muse, mutect2
- SREBF1 | c.2264C>A p.S755* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99889118; called by muse, mutect2
- SSH3 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs144805023, COSV100354655; called by muse, mutect2, varscan2
- SYCP2 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698345; called by muse, mutect2
- THEMIS | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965443; called by muse, mutect2, varscan2
- TNRC18 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1304723338; called by muse, mutect2
- TOR1A | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs755593280, COSV61029362; called by muse, mutect2, varscan2
- TSPYL2 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100966327; called by muse, mutect2, varscan2
- USH2A | c.5497G>T p.V1833L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV100238070; called by muse, mutect2
- USP53 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917862; called by muse, mutect2, varscan2
- WNK3 | c.4612C>T p.Q1538* | Nonsense Mutation (SNP) | VAF 15/299 reads (5%) | catalogued as COSV100671648; called by muse, mutect2
- ZBBX | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs755917643, COSV56801671; called by muse, mutect2
- ZNF35 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.23); catalogued as rs772530497, COSV99940103; called by muse, mutect2, varscan2
- ZNF425 | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100955519, COSV65200979; called by muse, mutect2
- ZNF669 | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100594293; called by muse, mutect2, varscan2
- GLI4 | c.565_575del p.G189Qfs*3 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- KCNK4 | c.313_313+18del p.X105_splice | Splice Site (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- PDGFRA | c.1512_1514del p.K504del | In Frame Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- PELP1 | c.3329C>G p.A1110G | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- STRA6 | c.709_716del p.A237Qfs*9 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel
- SUCLG2 | c.503_519del p.V168Gfs*5 | Frame Shift Del (DEL) | VAF 16/172 reads (9%) | called by mutect2, pindel
- ABCA2 | c.2757C>T p.D919= (on ENST00000614293; = p.D889= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs202178377, COSV55807592; called by muse, mutect2, varscan2
- C2orf78 | c.525C>T p.V175= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs766766567, COSV101280997; called by muse, mutect2, varscan2
- DCDC1 | c.4935T>C p.N1645= (on ENST00000597505 / NM_001367979.1; = p.N752= on NM_020869.3) | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV100360665; called by muse, mutect2, varscan2
- DPYS | c.1245A>T p.S415= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100679843; called by muse, mutect2
- GRM8 | c.1596C>A p.V532= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100284228, COSV58856965; called by muse, mutect2, varscan2
- HYAL4 | c.270T>C p.F90= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV99772328; called by muse, mutect2
- LRP1B | c.7914G>C p.V2638= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as rs959486756, COSV101257993, COSV67187457; called by muse, mutect2
- LYG2 | c.261C>T p.V87= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs573670949, COSV100283711; called by muse, mutect2, varscan2
- NRP1 | c.756G>A p.A252= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1375059208, COSV55164984; called by muse, mutect2
- PHF2 | c.996C>T p.F332= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV63681054; called by muse, mutect2, varscan2
- PKDREJ | c.684C>T p.G228= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs1464705925, COSV53551239; called by muse, mutect2, varscan2
- RORA | c.1362A>G p.Q454= (on ENST00000335670 / NM_134261.3; = p.Q479= on NM_002943.3) | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV99832850; called by muse, mutect2
- SHISA4 | c.234C>T p.C78= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100748251; called by muse, mutect2
- TNRC18 | c.2568C>T p.G856= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV101269765; called by muse, mutect2, varscan2
- UBE2O | c.2676C>T p.P892= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs574632752; called by muse, mutect2
- VPS37D | c.345G>A p.A115= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs782771456, COSV100265309; called by muse, mutect2
- ZNF2 | c.48C>T p.F16= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs372212740, COSV54637629; called by muse, mutect2, varscan2
- AC024940.1 | n.4261C>T | RNA (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- AL353804.4 | chrX:73823628 C>T | 5'Flank (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ANKRD54 | chr22:37847722 del CTGTGACTCTTCCTTGGTTCAGGGAAGGTC | 5'Flank (DEL) | VAF 13/148 reads (9%) | called by mutect2, pindel
- DLG3 | c.1145+678C>T | Intron (SNP) | VAF 16/218 reads (7%) | catalogued as COSV52082720, COSV99529806; called by muse, mutect2
- PDLIM7 | c.572+318G>C | Intron (SNP) | VAF 36/130 reads (28%) | catalogued as COSV100730265; called by muse, mutect2, varscan2
